Surgical pathology report (de-identified scan), TCGA case TCGA-J4-A83J, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-A83J-01A (Primary Tumor).

[page 1 of 4]
MRN

Name

Encounter
Number

Gender

Date Of
Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
StatusTime Received
Order Number

Results

Source of Specimen

- A. LEFT LYMPH NODES FS-
- B. LEFT LYMPH NODES NFS-
- C. PROSTATE GLAND-
- D. BLADDER NECK FS-

FINAL DIAGNOSIS:

- A. LEFT LYMPH NODES FS-
REACTIVE LYMPH NODE FRAGMENTS, NO TUMOR SEEN, 0/1.
- B. LEFT LYMPH NODES NFS-
FRAGMENTS OF REACTIVE LYMPH NODE AND FAT, NO CARCINOMA
IDENTIFIED.
- C. PROSTATE GLAND-
ADENOCARCINOMA OF PROSTATE.

TUMOR SITE: LEFT AND RIGHT PROSTATE, MOSTLY IN PERIPHERAL ZONE.

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 30 GRAMS. SIZE: 4 x 3.5 x 3.0 CM.

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 3 + 4 = 7/10.

TERTIARY PATTERN: IS NOT PRESENT.

SEVERITY IN EXTENT OF TUMOR: 4 / 5.

(1: <5%; 2: 5-15%; 3: 15-30%; 4: 30-50%; 5: > 50% tissue

ONE ICD O-3 Final
Adenocarcinoma, acinar 8140/3
path Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9
9/11/24/13

[page 2 of 4]
involvement).

DOMINANT NODULE (AT LEAST 1 CM IN SIZE): IS PRESENT, 1.1 CM IN SIZE.

TREATMENT EFFECT ON CARCINOMA: IS NOT IDENTIFIED.

TNM STAGE: AT LEAST pt2c (SEE COMMENT), pN0, pMX.

LYMPHATIC (SMALL VESSEL) INVASION: IS NOT SEEN.

PERINEURAL INVASION: IS PRESENT.

NO TUMOR SEEN IN SEMINAL VESICLES.

MARGIN STATUS:

POSITIVE INKED MARGINS: THERE IS A SMALL FOCUS OF TUMOR AT THE INKED MARGIN OF THE RIGHT PROSTATIC APEX. ALSO, SECTIONS OF THE INKED BLADDER NECK MARGIN SHOW TUMOR TO BE VERY CLOSE (< 0.1 CM) TO THE MARGIN ON THE LEFT AND THE RIGHT. HOWEVER, NO CARCINOMA IS SEEN IN BLADDER NECK FS SPECIMEN (PART D), WHICH PRESUMABLY REPRESENTS THE TRUE, FINAL BLADDER NECK MARGIN. SEE COMMENT.

OTHER CAPSULAR MARGINS ARE CLEAR.

COMMENT: THE POSITIVE MARGIN APPEARS TO BE DISRUPTED BY AN IATROGENIC INCISION. THERE IS NO EXTRAPROSTATIC INVASION SEEN ELSEWHERE. FURTHER CLINICAL CORRELATION IS RECOMMENDED.

D. BLADDER NECK FS-

PROSTATE TISSUE AND SMOOTH MUSCLE, NO CARCINOMA IDENTIFIED.

Signed Others

Frozen Section

A. LEFT LYMPH NODE- ONE FATTY LYMPH NODE, REPRESENTATIVE SECTIONS FOR FROZEN SECTION.

FROZEN SECTION: NO CARCINOMA SEEN.

BLADDER NECK- MUSCULAR AND PROSTATE TISSUE. NO TUMOR SEEN.

Frozen section performed by

[page 3 of 4]
Case Clinical Information
PROSTATE CANCER

Gross Description

- A. Received in formalin labeled with the patient's name and "left lymph node-FS" are six fatty nodes measuring up to 0.8 cm. All material submitted in A1.
- B. Received in formalin labeled with the patient's name and "left lymph nodes-NFS" are multiple fragments of finely divided fat measuring 1.5 x 1.5 x 1.5 cm in compact aggregate. All material submitted in B1-B2.
- C. Received in formalin labeled with the patient's name and "prostate gland" is a 30 gram prostate, previously inked blue on the right and black on the left, partially bisected distally, measuring 4 cm. right to left, 3.5 cm. anterior to posterior and 3.0 cm. superior to inferior. Right and left seminal vesicles measure 2 x 1 x 0.6 cm and 2.5 x 1.5 x 0.8 cm. Segments of right and left vas measure 1 x 0.3 cm and 1.5 x 0.3 cm. The distal urethral margin and proximal bladder margin are amputated from the remainder of the specimen. These shall be totally submitted after sectioning parallel to the urethra anterior to posterior. The remaining gland shows firm, focally nodular parenchyma. Entire gland submitted. Section code: C1-C3= distal urethral margin totally submitted anterior to posterior; first additional slice anterior lobes C4-C5; posterior C6-C7; second additional section anterior lobes C8-C9; posterior C10-C11; third additional slice anterior lobes C12-C13; posterior C14-C15; bladder margin totally submitted anterior periurethral margin in C16 proceeding to posterior in C17-C18; left seminal vesicle and vas in C19; right seminal vesicle and vas in C20.
- D. Received in formalin labeled with the patient's name and "bladder neck-FS" are two yellow-tan tissues measuring up to 0.8 cm in greatest dimension. Totally submitted in D1.
- [REDACTED]

Procedure

- A. AA ROUTINE H&E X1 BLOCK
H&E X1
- B. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- B. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- C. AA ROUTINE H&E X1 BLOCK.1
- [REDACTED]

[page 4 of 4]
H&E X1 A RECUTS
C. AA ROUTINE H&E X1 BLOCK.2
H&E X1
C. AA ROUTINE H&E X1 BLOCK.3
H&E X1
C. AA ROUTINE H&E X1 BLOCK.4
H&E X1
C. AA ROUTINE H&E X1 BLOCK.5
H&E X1
C. AA ROUTINE H&E X1 BLOCK.6
H&E X1
C. AA ROUTINE H&E X1 BLOCK.7
H&E X1
C. AA ROUTINE H&E X1 BLOCK.8
H&E X1
C. AA ROUTINE H&E X1 BLOCK.9
H&E X1
C. AA ROUTINE H&E X1 BLOCK.10
H&E X1
C. AA ROUTINE H&E X1 BLOCK.11
H&E X1
C. AA ROUTINE H&E X1 BLOCK.12
H&E X1
C. AA ROUTINE H&E X1 BLOCK.13
H&E X1
C. AA ROUTINE H&E X1 BLOCK.14
H&E X1
C. AA ROUTINE H&E X1 BLOCK.15
H&E X1 AA RECUT
C. AA ROUTINE H&E X1 BLOCK.16
H&E X1 AA RECUT
C. AA ROUTINE H&E X1 BLOCK.17
H&E X1
C. AA ROUTINE H&E X1 BLOCK.18
H&E X1
C. AA ROUTINE H&E X1 BLOCK.19
H&E X1
C. AA ROUTINE H&E X1 BLOCK.20
H&E X1
D. AA ROUTINE H&E X1 BLOCK
H&E X1

Source: NCI Genomic Data Commons file ca4470f9-8d7d-47be-8ece-b6bc5870d3c9 (TCGA-J4-A83J.D3FF2CCF-E6D0-4C8A-9159-F78176E7EE59.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).